Somatic mutation profile of tumor specimen TCGA-AG-3909-01A (aliquot TCGA-AG-3909-01A-01W-1073-09) from TCGA case TCGA-AG-3909, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.9 years (25,537 days).
Specimen TCGA-AG-3909-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c161a3ac-83b1-4541-9727-8a72add94c6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3909-10A (Blood Derived Normal), aliquot TCGA-AG-3909-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/121528a4-f4f7-4a08-8350-9c9c2b831176

The open-access MAF lists 84 somatic variants for this specimen: 71 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 12, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 109/157 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2257C>A p.H753N (on ENST00000272895 / NM_173076.3; = p.H435N on NM_015657.3) | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as COSV55971206; called by muse, mutect2, varscan2
- ABCC5 | c.2636G>A p.W879* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV55594903; called by muse, mutect2, varscan2
- ADCY1 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as rs368928291; called by muse, mutect2, varscan2
- AK7 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767851012, COSV50879282; called by muse, mutect2, varscan2
- ANK3 | c.9959A>G p.D3320G | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as rs1173029125, COSV99779605; called by muse, mutect2, varscan2
- APC | c.2489del p.V830Gfs*12 | Frame Shift Del (DEL) | VAF 70/217 reads (32%) | catalogued as COSV57370092; called by mutect2, pindel, varscan2
- APC | c.7292G>A p.R2431K | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as rs879254262, COSV57370109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC2 | c.656T>A p.L219* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99770260; called by muse, mutect2, varscan2
- ATP2C2 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV52299980; called by muse, mutect2, varscan2
- ATP6V1C2 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV99695716; called by muse, mutect2
- BANK1 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 48/96 reads (50%) | catalogued as rs761921169, COSV59847272; called by muse, mutect2
- CAND2 | c.1879C>T p.R627W (on ENST00000456430 / NM_001162499.2; = p.R534W on NM_012298.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754877644, COSV55993296; called by muse, mutect2, varscan2
- CAPZA1 | c.260T>G p.F87C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV54146734; called by muse, mutect2, varscan2
- CD177 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65122258; called by muse, mutect2, varscan2
- CFAP221 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776819889, COSV54661111; called by muse, mutect2, varscan2
- CHRNA1 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV53684538; called by muse, mutect2, varscan2
- CMTM2 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.531); catalogued as rs1320821229, COSV51749451; called by muse, mutect2
- COBLL1 | c.694C>G p.Q232E (on ENST00000392717; = p.Q194E on NM_014900.5) | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52068441, COSV52074317; called by muse, mutect2, varscan2
- COL7A1 | c.4096C>T p.R1366W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs147089666, CM137501; called by muse, mutect2, varscan2
- COLEC12 | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68372873; called by muse, mutect2, varscan2
- DENND3 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs778334141, COSV52805445; called by muse, mutect2, varscan2
- DIO2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs773948064, COSV70446063; called by muse, mutect2, varscan2
- DMD | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0910024, COSV55854466, COSV55883347; called by muse, mutect2, varscan2
- DNAH10 | c.995C>T p.P332L (on ENST00000409039; = p.P271L on NM_207437.3) | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs775539811, COSV68999212; called by muse, mutect2, varscan2
- DNAH2 | c.6541G>A p.V2181I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs147226714; called by muse, mutect2, varscan2
- DPYD | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV64608203; called by muse, mutect2, varscan2
- FAT2 | c.3991C>T p.R1331W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746994544, COSV55819142; called by muse, mutect2, varscan2
- FAT2 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55826963; called by muse, mutect2, varscan2
- FBXO40 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs141957650, COSV57525207; called by muse, mutect2, varscan2
- GRIN2A | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58051378; called by muse, mutect2, varscan2
- GRM5 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.259); catalogued as rs1223898699, COSV59621609; called by muse, mutect2, varscan2
- GUCA1C | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs1478411182, COSV51727859; called by muse, mutect2
- HCCS | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58239504; called by muse, mutect2, varscan2
- HEATR1 | c.4975G>A p.G1659R | Missense Mutation (SNP) | VAF 176/248 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV63982612; called by muse, mutect2, varscan2
- HEATR5B | c.6214dup p.*2072Lfs*18 | Frame Shift Ins (INS) | VAF 37/89 reads (42%) | catalogued as rs1315552549; called by mutect2, varscan2
- HERC2 | c.3266T>A p.L1089Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55343301; called by muse, mutect2, varscan2
- KCNK1 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64035956; called by muse, mutect2, varscan2
- LRP1B | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 196/456 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs371410109; called by muse, mutect2, varscan2
- MCF2L2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV61059309; called by muse, mutect2, varscan2
- MDFI | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100025651; called by muse, mutect2
- MMP9 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs1291812181, COSV63434152; called by muse, mutect2
- MPEG1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1049528735, COSV57093897; called by muse, varscan2
- MYO10 | c.4464G>T p.W1488C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57027571; called by muse, mutect2, varscan2
- NEXMIF | c.4018C>A p.P1340T | Missense Mutation (SNP) | VAF 156/335 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50075772; called by muse, mutect2, varscan2
- NRXN1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs796052764, COSV58439539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5L1 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61735024; called by muse, mutect2, varscan2
- PCDH9 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60565277; called by muse, mutect2, varscan2
- PCDHA2 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as rs1239286349, COSV65366784; called by muse, mutect2, varscan2
- PCIF1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1373444161, COSV100976047; called by muse, mutect2, varscan2
- PRAMEF17 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs769537184, COSV101068724; called by muse, mutect2, varscan2
- PTCRA | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58975812, COSV58976584; called by muse, mutect2, varscan2
- RSPRY1 | c.404-1G>T p.X135_splice | Splice Site (SNP) | VAF 13/135 reads (10%) | catalogued as COSV101070994; called by muse, mutect2
- RYR2 | c.5387C>A p.T1796K | Missense Mutation (SNP) | VAF 263/533 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV63705766; called by muse, mutect2, varscan2
- SEMA3E | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs773917768, COSV57103792; called by muse, mutect2, varscan2
- SGO1 | c.1489G>A p.D497N (on ENST00000263753 / NM_001012410.5; = p.D228N on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55424685; called by muse, mutect2, varscan2
- SLC4A5 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs771484697, COSV61031063, COSV61031434; called by muse, mutect2, varscan2
- SPATA31E1 | c.4154G>A p.G1385D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.147); catalogued as rs1247784469, COSV57794292; called by muse, mutect2, varscan2
- SYNE1 | c.5413C>T p.R1805W (on ENST00000367255 / NM_182961.4; = p.R1812W on NM_033071.3) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs763781396, COSV99561846; called by muse, mutect2, varscan2
- TENT2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV57138879; called by muse, varscan2
- TEX11 | c.2752C>A p.L918I (on ENST00000344304; = p.L903I on NM_031276.3) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.3); catalogued as COSV60236714; called by muse, mutect2, varscan2
- TRIML2 | c.1059G>C p.W353C | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58718694, COSV58720085; called by muse, mutect2, varscan2
- TTN | c.65405G>A p.R21802Q (on ENST00000591111; = p.R14378Q on NM_003319.4) | Missense Mutation (SNP) | VAF 44/147 reads (30%) | PolyPhen benign (0.052); catalogued as rs762529671, COSV60264572; called by muse, mutect2, varscan2
- TTN | c.47567A>G p.N15856S (on ENST00000591111; = p.N8432S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | PolyPhen probably damaging (0.994); catalogued as COSV60264591; called by muse, mutect2, varscan2
- TTN | c.40021A>T p.K13341* (on ENST00000591111; = p.K5917* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV59973208, COSV60264613; called by muse, mutect2, varscan2
- ZNF578 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV69736932, COSV69737323; called by muse, mutect2, varscan2
- APC | c.3880_3881del p.Q1294Gfs*6 | Frame Shift Del (DEL) | VAF 71/250 reads (28%) | called by pindel, varscan2
- HYOU1 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, mutect2
- TCF7L2 | c.1139_1145del p.I380Rfs*65 (on ENST00000355995 / NM_001367943.1; = p.I357Rfs*65 on NM_030756.5) | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by pindel, varscan2*
- TSPYL4 | c.1042_1046del p.G348Hfs*4 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by pindel, varscan2
- ZNF544 | c.1470dup p.P491Tfs*16 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.3171C>T p.V1057= | Silent (SNP) | VAF 38/234 reads (16%) | catalogued as rs187998780, COSV51421141; called by muse, mutect2, varscan2
- ARFRP1 | c.111G>A p.S37= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs528376535, COSV60833143; called by muse, mutect2, varscan2
- ASB15 | c.1560A>G p.V520= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as COSV99306463; called by muse, mutect2
- CATSPERG | c.1755C>T p.S585= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53052314; called by muse, mutect2, varscan2
- DCAF12L2 | c.849C>T p.D283= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1054703704, COSV63583731; called by muse, mutect2, varscan2
- OR2A14 | c.666C>T p.A222= | Silent (SNP) | VAF 100/342 reads (29%) | catalogued as rs773698940, COSV101376494, COSV68718477, COSV68718683; called by muse, mutect2, varscan2
- PROS1 | c.774T>C p.N258= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV67776689; called by muse, mutect2, varscan2
- TIAM1 | c.3267G>A p.T1089= | Silent (SNP) | VAF 53/216 reads (25%) | catalogued as rs143851539; called by muse, mutect2, varscan2
- TIMELESS | c.1971G>A p.Q657= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV57514244; called by muse, mutect2, varscan2
- TMEM132D | c.1200G>A p.T400= | Silent (SNP) | VAF 167/249 reads (67%) | catalogued as rs1392091331, COSV70618784; called by muse, mutect2, varscan2
- TRPC7 | c.324C>T p.D108= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs752389161, COSV61462018; called by muse, mutect2, varscan2
- WDR36 | c.60G>T p.V20= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs760274851, COSV72411409; called by muse, mutect2, varscan2
- SNORD3B-1 | n.33G>C | RNA (SNP) | VAF 13/29 reads (45%) | catalogued as rs1482971157; called by muse, mutect2, varscan2
